Gene-level copy-number profile of tumor specimen TCGA-24-1844-01A from TCGA case TCGA-24-1844, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 64.5 years (23,542 days).
Specimen TCGA-24-1844-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d40bb484-46c5-48dd-8394-7e503053f1a1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1844-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bed7547-88ac-4b7a-80a0-0c12fd73d492

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,413; copy number 2: 7,449; copy number 3: 14,632; copy number 4: 22,725; copy number 5: 8,792; copy number 6: 1,687; copy number 7: 935; copy number 9: 19; copy number 11: 90; copy number 12: 69; copy number 15: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1844-01A-01D-0577-01): tumor purity 0.86, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 22 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:31,639,222–32,855,666, 1 gene, copy number 9 (within-gene range 3–17): NRG1.
- chr8:32,026,210–32,647,390, 5 genes, copy number 9–15 (within-gene range 9–17): NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1.
- chr19:13,206,442–13,906,452, 16 genes, copy number 9 (within-gene range 7–9): CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57.

Autosomal genes at a single copy (total copy number 1): 2,331. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
